Somatic mutation profile of tumor specimen TCGA-A3-3382-01A (aliquot TCGA-A3-3382-01A-01W-0886-08) from TCGA case TCGA-A3-3382, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 69.0 years (25,207 days).
Specimen TCGA-A3-3382-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9c00561-4e14-4681-bb2d-7f8495cb7550.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3382-11A (Solid Tissue Normal), aliquot TCGA-A3-3382-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d69d38f8-ed63-4b33-a9d9-624edcfd5245

The open-access MAF lists 127 somatic variants for this specimen: 103 protein-altering or splice-affecting, 20 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 20, Nonsense Mutation 11, Frame Shift Del 7, In Frame Del 3, Frame Shift Ins 3, Intron 2, Splice Site 2, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.343C>A p.H115N | Missense Mutation (SNP) | VAF 143/224 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as CD141839, CM961423, CM982005, COSV56545369, COSV56546151, COSV56556158, COSV56571206; called by muse, mutect2, varscan2
- AICDA | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 86/323 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV57563789, COSV57564692; called by muse, mutect2, varscan2
- AMOTL2 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs547887711; called by muse, mutect2, varscan2
- ANGPTL1 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 41/368 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV52365109; called by muse, mutect2, varscan2
- ATP1A1 | c.1171A>G p.M391V | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as rs1252478023; called by muse, mutect2, varscan2
- C1orf94 | c.1234C>T p.R412* (on ENST00000488417 / NM_001134734.2; = p.R222* on NM_032884.5) | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | catalogued as rs775448857, COSV64914334; called by muse, mutect2, varscan2
- CASP10 | c.625C>A p.Q209K | Missense Mutation (SNP) | VAF 309/1285 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs895371405, COSV53778786; called by muse, mutect2, varscan2
- CTSE | c.517A>T p.S173C (on ENST00000360218; = p.S168C on NM_001910.4) | Missense Mutation (SNP) | VAF 65/543 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63059956; called by muse, mutect2, varscan2
- DNAH3 | c.1961C>A p.S654Y | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT tolerated (0.88); PolyPhen benign (0.011); catalogued as COSV54521719, COSV54532850; called by muse, varscan2
- E2F8 | c.2137G>A p.G713R | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.657); catalogued as rs754334957, COSV100001551, COSV51463335; called by muse, mutect2, varscan2
- FAM83E | c.889dup p.Q297Pfs*33 | Frame Shift Ins (INS) | VAF 8/49 reads (16%) | catalogued as rs773971919; called by mutect2, varscan2
- FRMD4A | c.3014dup p.S1006Kfs*25 | Frame Shift Ins (INS) | VAF 26/235 reads (11%) | catalogued as rs752538869; called by mutect2, varscan2
- GOLIM4 | c.1013A>C p.E338A | Missense Mutation (SNP) | VAF 235/338 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs1358541995, COSV58327947; called by muse, mutect2, varscan2
- KCNU1 | c.2248G>A p.D750N | Missense Mutation (SNP) | VAF 46/607 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs758762776, COSV101299272; called by muse, mutect2
- KIF16B | c.3169C>G p.Q1057E | Missense Mutation (SNP) | VAF 263/810 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.036); catalogued as COSV61716773; called by muse, mutect2, varscan2
- LRRC32 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs370963014, COSV99477004; called by muse, mutect2, varscan2
- MAP2K7 | c.1156C>A p.L386M | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as rs764054804, COSV67609313; called by muse, mutect2, varscan2
- MFSD6 | c.835T>C p.Y279H | Missense Mutation (SNP) | VAF 245/856 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs777184056; called by muse, mutect2, varscan2
- MSC | c.371G>C p.S124T | Missense Mutation (SNP) | VAF 55/82 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV57696553; called by muse, mutect2
- OR2L8 | c.180C>G p.F60L | Missense Mutation (SNP) | VAF 865/2225 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as COSV61728485; called by muse, varscan2
- OR2T12 | c.379C>G p.P127A | Missense Mutation (SNP) | VAF 36/370 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207273678, COSV99040529; called by muse, varscan2
- PBRM1 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 45/116 reads (39%) | catalogued as COSV56264253; called by muse, mutect2, varscan2
- SCG3 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 25/240 reads (10%) | catalogued as COSV55020862; called by muse, mutect2, varscan2
- SCNN1A | c.1757G>A p.R586Q | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.163); catalogued as rs545954539; called by muse, mutect2, varscan2
- SMARCA1 | c.1819C>T p.R607* | Nonsense Mutation (SNP) | VAF 50/178 reads (28%) | catalogued as COSV64414082; called by muse, mutect2, varscan2
- SSRP1 | c.1479G>A p.E493= | Splice Region (SNP) | VAF 23/146 reads (16%) | catalogued as rs1424303401, COSV53481879; called by muse, mutect2, varscan2
- UNC45B | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.953); catalogued as rs778484839; called by muse, mutect2, varscan2
- ZNF347 | c.1628G>T p.C543F | Missense Mutation (SNP) | VAF 159/433 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100498311; called by muse, mutect2, varscan2
- ZNF451 | c.2330A>C p.K777T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV62597730; called by muse, mutect2, varscan2
- A1CF | c.867+1del p.X289_splice | Splice Site (DEL) | VAF 10/80 reads (13%) | called by mutect2, varscan2
- AADACL3 | c.991G>C p.D331H | Missense Mutation (SNP) | VAF 100/444 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ABCA12 | c.2680C>A p.L894I (on ENST00000272895 / NM_173076.3; = p.L576I on NM_015657.3) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- ADAM19 | c.1033C>T p.H345Y | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1147_1156del p.V383Wfs*18 | Frame Shift Del (DEL) | VAF 39/123 reads (32%) | called by mutect2, pindel, varscan2
- ANGPTL7 | c.348del p.A117Hfs*105 | Frame Shift Del (DEL) | VAF 29/202 reads (14%) | called by mutect2, pindel, varscan2
- ANKRD44 | c.1209dup p.F404Ifs*14 | Frame Shift Ins (INS) | VAF 61/220 reads (28%) | called by mutect2, pindel, varscan2
- ARNTL | c.91A>G p.S31G | Missense Mutation (SNP) | VAF 64/299 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, varscan2
- ATP13A5 | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 37/331 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- ATPAF2 | c.480_482del p.I162del | In Frame Del (DEL) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- B9D1 | c.365T>G p.F122C | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- C16orf71 | c.149A>C p.E50A | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- CDK2 | c.492_495delinsCA p.L166Vfs*6 | Frame Shift Del (DEL) | VAF 45/220 reads (20%) | called by pindel, varscan2*
- CEP63 | c.1631C>G p.P544R | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- CEP83 | c.700T>A p.L234I | Missense Mutation (SNP) | VAF 112/307 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD5 | c.5303T>A p.L1768H | Missense Mutation (SNP) | VAF 61/81 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CPLX2 | c.222G>T p.K74N | Missense Mutation (SNP) | VAF 91/146 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DCDC1 | c.2791G>T p.E931* (on ENST00000597505 / NM_001367979.1; = p.E38* on NM_020869.3) | Nonsense Mutation (SNP) | VAF 65/98 reads (66%) | called by muse, mutect2, varscan2
- DENND5A | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.062); called by muse, mutect2
- DMD | c.9334C>A p.L3112I | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- DMXL2 | c.3772G>C p.G1258R | Missense Mutation (SNP) | VAF 262/461 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJB4 | c.329T>C p.I110T | Missense Mutation (SNP) | VAF 90/409 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EIF3L | c.514G>C p.G172R | Missense Mutation (SNP) | VAF 65/211 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- ENHO | c.65T>G p.L22W | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ENO1 | c.495G>T p.M165I | Missense Mutation (SNP) | VAF 375/580 reads (65%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- EPYC | c.350C>G p.T117S | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- FAM217A | c.405G>T p.K135N | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- FBN1 | c.1213C>A p.P405T | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FRS2 | c.505del p.S169Lfs*10 | Frame Shift Del (DEL) | VAF 78/410 reads (19%) | called by mutect2, pindel, varscan2
- GLDC | c.2728del p.S910Rfs*14 | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | called by mutect2, pindel
- GPR65 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GULP1 | c.844-1G>A p.X282_splice | Splice Site (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- HFM1 | c.1753T>C p.Y585H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSP90AB1 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- HSPA12A | c.1689G>C p.W563C | Missense Mutation (SNP) | VAF 61/93 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HTT | c.866_878del p.S289Mfs*4 | Frame Shift Del (DEL) | VAF 36/180 reads (20%) | called by mutect2, pindel, varscan2
- IFT140 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, varscan2
- IPP | c.1333_1341del p.I445_N447del | In Frame Del (DEL) | VAF 25/75 reads (33%) | called by mutect2, pindel, varscan2
- KAT6B | c.2557T>A p.Y853N | Missense Mutation (SNP) | VAF 52/278 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- LDHAL6B | c.37A>T p.R13* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2
- MAP4 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 117/257 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- NF1 | c.8226C>G p.Y2742* (on ENST00000358273 / NM_001042492.3; = p.Y2721* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 126/285 reads (44%) | called by muse, mutect2, varscan2
- OR10S1 | c.38C>A p.T13K | Missense Mutation (SNP) | VAF 38/1400 reads (3%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- OTOF | c.1735G>C p.D579H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PARP4 | c.1423G>A p.G475R | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDLIM4 | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PHF12 | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- PHTF1 | c.1254G>T p.E418D | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT tolerated (0.89); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- PIGG | c.2199C>A p.C733* (on ENST00000453061 / NM_001127178.3; = p.C725* on NM_017733.4) | Nonsense Mutation (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- PITRM1 | c.2882C>A p.S961* | Nonsense Mutation (SNP) | VAF 40/537 reads (7%) | called by muse, mutect2
- POLK | c.1528G>A p.G510S | Missense Mutation (SNP) | VAF 129/196 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRDM10 | c.3202C>A p.P1068T | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RIF1 | c.2731C>G p.Q911E | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- RSRP1 | c.295_300del p.G99_F100del | In Frame Del (DEL) | VAF 11/58 reads (19%) | called by mutect2, pindel, varscan2
- SCN10A | c.1402G>T p.E468* | Nonsense Mutation (SNP) | VAF 172/673 reads (26%) | called by muse, mutect2, varscan2
- SLC7A14 | c.1886C>A p.A629D | Missense Mutation (SNP) | VAF 30/640 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPEF2 | c.2274del p.K758Nfs*27 | Frame Shift Del (DEL) | VAF 66/169 reads (39%) | called by mutect2, pindel, varscan2
- STRBP | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 71/128 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TAF1L | c.3017C>T p.T1006I | Missense Mutation (SNP) | VAF 15/530 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2
- TARS2 | c.1645G>A p.G549S | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCOF1 | c.570G>T p.M190I | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- TIAM2 | c.4454A>C p.E1485A (on ENST00000529824; = p.E1456A on NM_012454.3) | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- TNK1 | c.1603G>T p.G535C (on ENST00000576812 / NM_001251902.2; = p.G530C on NM_003985.5) | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- TRPC7 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 200/464 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- TTN | c.97832G>A p.R32611K (on ENST00000591111; = p.R25187K on NM_003319.4) | Missense Mutation (SNP) | VAF 10/204 reads (5%) | PolyPhen benign (0.122); called by muse, mutect2
- TTN | c.13945G>A p.A4649T (on ENST00000591111; = p.A3722T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/89 reads (42%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TUBB1 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- UBA7 | c.1844C>A p.A615D | Missense Mutation (SNP) | VAF 77/111 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USH2A | c.3171A>C p.Q1057H | Missense Mutation (SNP) | VAF 118/428 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- UTRN | c.2560A>G p.K854E | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- WDTC1 | c.838G>C p.G280R | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WIPI2 | c.1345A>G p.M449V | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF292 | c.7543C>T p.Q2515* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- ZNF781 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 26/400 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- CASQ1 | c.36G>A p.V12= | Silent (SNP) | VAF 32/204 reads (16%) | called by muse, mutect2, varscan2
- CPOX | c.882C>T p.V294= | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- CYFIP2 | c.1383G>A p.Q461= | Silent (SNP) | VAF 185/537 reads (34%) | called by muse, mutect2, varscan2
- EHD3 | c.939T>C p.S313= | Silent (SNP) | VAF 129/781 reads (17%) | catalogued as rs1292812843; called by muse, mutect2, varscan2
- FOXK1 | c.1107C>G p.S369= | Silent (SNP) | VAF 8/99 reads (8%) | catalogued as rs1293216391; called by muse, mutect2
- GALNT3 | c.1593T>A p.I531= | Silent (SNP) | VAF 38/123 reads (31%) | called by muse, mutect2, varscan2
- GLCCI1 | c.1482T>G p.V494= | Silent (SNP) | VAF 195/807 reads (24%) | called by muse, mutect2, varscan2
- LTBP2 | c.3945C>T p.S1315= | Silent (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- MAVS | c.876C>T p.N292= | Silent (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- MRM2 | c.645A>T p.V215= | Silent (SNP) | VAF 58/116 reads (50%) | called by muse, mutect2, varscan2
- NF1 | c.2442G>A p.K814= | Silent (SNP) | VAF 79/186 reads (42%) | called by muse, mutect2, varscan2
- OR2T27 | c.696G>A p.E232= | Silent (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- PDP2 | c.180C>T p.C60= | Silent (SNP) | VAF 28/232 reads (12%) | called by muse, mutect2, varscan2
- PLTP | c.1023C>A p.G341= | Silent (SNP) | VAF 52/210 reads (25%) | called by muse, varscan2
- RAD23B | c.840G>A p.R280= | Silent (SNP) | VAF 7/163 reads (4%) | called by muse, mutect2
- SMC3 | c.174A>G p.P58= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100699965; called by muse, mutect2, varscan2
- SNRPB | c.9G>T p.V3= | Silent (SNP) | VAF 121/452 reads (27%) | called by muse, mutect2, varscan2
- VPS11 | c.186C>T p.A62= (on ENST00000620429; = p.A606= on NM_021729.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 53/335 reads (16%) | catalogued as rs781935851; called by muse, mutect2, varscan2
- WDFY3 | c.2028G>C p.V676= | Silent (SNP) | VAF 54/169 reads (32%) | called by muse, mutect2, varscan2
- ZNF618 | c.2394G>A p.V798= (on ENST00000374126 / NM_001318042.2; = p.V705= on NM_133374.2) | Silent (SNP) | VAF 16/332 reads (5%) | called by muse, mutect2
- CABYR | c.*17-187C>A | Intron (SNP) | VAF 34/574 reads (6%) | catalogued as COSV100111225; called by muse, mutect2
- CERS6 | c.1002+589C>T | Intron (SNP) | VAF 62/215 reads (29%) | called by muse, mutect2, varscan2
- FOLH1B | n.1680dup | RNA (INS) | VAF 65/220 reads (30%) | called by mutect2, pindel, varscan2
- SNORD52 | n.15C>T | RNA (SNP) | VAF 40/154 reads (26%) | called by muse, mutect2, varscan2
